Gene-level copy-number profile of tumor specimen TCGA-G4-6310-01A from TCGA case TCGA-G4-6310, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.1 years (25,243 days).
Specimen TCGA-G4-6310-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.af6da91e-c5d5-4841-b22f-42b50b717298.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6310-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eee8bd69-cd29-4d72-9e5c-705d70144703

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 569; copy number 2: 6,239; copy number 3: 31,364; copy number 4: 13,047; copy number 5: 2,692; copy number 6: 1,064; copy number 7: 2,192; copy number 8: 1,376; copy number 9: 677; copy number 10: 172; copy number 12: 282; copy number 13: 110; copy number 14: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-G4-6310-01): tumor purity 0.55, ploidy 3.54, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–6,721,960, 4 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,840 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–72,447,151, 1,308 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:112,520,488–145,681,369, 687 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 8–9 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 9–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 569. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
